Surgical pathology report (de-identified scan), TCGA case TCGA-42-2591, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-42-2591-01A (Primary Tumor).

[page 1 of 6]
SPECIMEN

- A. Right tube and ovary
- B. Left tube and ovary
- C. Uterus and cervix
- D. Omentum
- E. Omental lymph node
- F. Right gutter peritoneal biopsy
- G. Paraaortic lymph node
- H. Right pelvic lymph node
- I. Left pelvic lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Ovarian cancer.

FROZEN SECTION DIAGNOSIS

- A) Right fallopian tube and ovary, excision - Serous carcinoma.
- B) Left fallopian tube and ovary, excision - Serous carcinoma.

GROSS DESCRIPTION

- A. Received fresh for frozen section labeled "right tube and ovary" is a 441 gram (post incision and fixation),

18.5

x 13.5 x 9.7 cm. bosselated white pink to tan yellow cystic structure with an associated, fimbriated, 7.5 cm. pink purple fallopian tube along one aspect. The tube ranges from 0.3 to 0.7 cm.

in diameter with a pinpoint stellate lumen on sectioning. On opening, the specimen is multiloculated containing grumous brown fluid and friable yellow white debris. Multiple soft to slightly rubbery tan white papillations are present throughout the locules which measure up to 14 cm. in greatest dimension. There is also a moderate solid component to the specimen (constituting approximately

40% of the overall volume), which is glistening to chalky tan white.

Two frozen sections are performed (see frozen section diagnosis). A portion of the specimen is submitted for tissue procurement as

[page 2 of 6]
GROSS DESCRIPTION

requested. Residual ovarian stroma is not identified.

Representative

sections are submitted in 18 blocks (fallopian tube represented in block 1). RS18.

B. Received fresh for frozen section labeled "left tube and ovary" is an 1188 (status post partial incision and fixation), 17.5 x 15.5 x 7.9 cm. bosselated dusky tan pink to tan white-purple cystic mass with an associated, fimbriated, 4.5 cm. pink purple fallopian tube averaging 0.7 cm. in diameter along one aspect. The specimen consists predominantly of glistening to chalky tan white-yellow red solid tumor with a few cystic locules containing yellow serous fluid. Two frozen sections are performed (see frozen section diagnosis). Soft tan pink papillations are evident within the larger locules. No residual ovarian stroma is identified. Representative sections are submitted in 17 blocks (fallopian tube represented in block 1). RS17.

C. Received fresh labeled "uterus and cervix" is a 93 gram, 6.5 cm. (superior to inferior) by 5.0 cm. (cornu to cornu) by 4.0 cm. (anterior to posterior) symmetrical uterine corpus with attached 3 cm. cervix. The serosa is smooth to slightly scabrous tan pink-red with a few tan red fibrous adhesions along the posterior aspect. The circular 2.7 cm. tan white ectocervix surrounds a 1.1 x 0.3 cm. ovoid patent os. Endocervical mucosa is moderately trabecular pale tan. The triangular, 3.6 x 2.5 uterine cavity is lined by flat pale tan pink endometrium averaging 0.2 cm. The myometrium is smooth pale tan pink and measures up to 2.4 cm. in thickness. No leiomyomata are present. Representative sections are submitted in 5 blocks as labeled. RS5.

BLOCK SUMMARY: 1 - Serosa; 2 - anterior cervix; 3 - posterior cervix; 4 - anterior endomyometrium; 5 - posterior endomyometrium.

D. Received fresh labeled "omentum" is a 41.0 x 8.5 x 1.0 cm. portion of soft, lobulated golden yellow adipose tissue in keeping with omentum. No discrete mass lesion or

[page 3 of 6]
GROSS DESCRIPTION

abnormality is identified. Random representative sections are submitted in 10 blocks. [REDACTED]

E. Received fresh labeled "omental lymph node" is an irregular, 7.6 x 3.5 x 1.0 cm. portion of soft, lobulated golden yellow adipose tissue with a slightly eccentric, 2.0 x 1.4 x 0.7 cm. rubbery tan white nodule (see blocks 1 and 2). Lymphoid tissue is not present. The specimen is entirely submitted in five blocks. [REDACTED]

F. Received fresh labeled "right gutter peritoneal biopsy"

is a focally cauterized, 3.1 x 2.3 x 0.2 cm. fragment of soft tan pink-red membranous tissue which is sectioned and entirely submitted in two blocks. [REDACTED]

G. Received fresh labeled "paraaortic lymph node" is a 4.5

x 2.6 x 0.9 cm. portion of soft, lobulated golden yellow adipose tissue. Six soft tan red tissues in keeping with lymph nodes measuring up to 3.5 cm. in greatest dimension are recovered. The lymphoid tissues are entirely submitted in four blocks as labeled. [REDACTED]

BLOCK SUMMARY: 1 - Three whole nodes; 2 and 3 - one bisected node per cassette; 4 - sectioned largest node.

H. Received fresh labeled "right pelvic lymph node" is a 4.9 x 4.5 x 1.9 cm. aggregate of soft, lobulated golden yellow adipose tissue. Eight soft tan red tissues in keeping with lymph nodes measuring up to 1.3 cm. in greatest dimension are recovered. The lymphoid tissues are entirely submitted in four blocks as labeled. [REDACTED]

BLOCK SUMMARY: 1 and 2 - Three whole lymph nodes per cassette; 4 and 5 - one bisected lymph node per cassette.

I. Received fresh labeled "left pelvic node" is a 6.2 x

[page 4 of 6]
[REDACTED]

GROSS DESCRIPTION

5.6 x 2.0 cm. aggregate of soft, lobulated golden yellow adipose tissue. Several intact to fragmented tan pink-red tissues in keeping with lymph nodes measuring up to 3.9 cm. in greatest dimension are recovered. The lymphoid tissues are entirely submitted in 6 blocks as labeled [REDACTED]

BLOCK SUMMARY: 1 - Seven whole nodes; 2 - five whole nodes; 3 - one bisected node; 4 - one trisected node; 5 and 6 - largest, fragmented [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Serous carcinoma with a prominent micropapillary pattern.

Primary tumor (pT) TNM (FIGO): Tumor is present in both ovaries and

metastatic into regional lymph nodes, PT3C

Sites of tumor beyond ovary in pelvis: Omental lymph node.

Regional lymph nodes [REDACTED]

Distant metastasis [REDACTED]

14x2, 15x2, 3x5, 4x4

DIAGNOSIS

A. Fallopian tube and ovary, right salpingo-oophorectomy - 18.5 cm.

ovary, extensively replaced by a serous carcinoma with a prominent micropapillary pattern.

Tumor is present on the surface of the ovary.

Fallopian tube, negative for tumor.

B. Fallopian tube and ovary, left salpingo-oophorectomy - 17.5 cm. ovary extensively replaced by a serous carcinoma with a prominent

[page 5 of 6]
DIAGNOSIS

micropapillary pattern.

Tumor is present on the surface of the ovary.

Fallopian tube negative for tumor.

- C. Uterus and cervix, hysterectomy - Atrophic endometrium.
Myometrium with no significant histopathologic abnormality.
Cervix with acute and chronic inflammation and reactive changes.

- D. Omentum, excision - Three lymph nodes negative for metastatic carcinoma (0/3).

Adipose tissue with chronic inflammation and reactive mesothelium.

- E. Soft tissue, omental lymph node, excision - Adipose tissue with metastatic serous carcinoma and chronic inflammation.

- F. Soft tissue, right gutter peritoneum, biopsy - Metastatic serous carcinoma.

- G. Lymph nodes, para-aortic, excision - One of six lymph nodes positive for metastatic adenocarcinoma (1/6).

- H. Lymph node, right pelvic, excision - Eight lymph nodes negative for metastatic carcinoma (0/8).

- I. Lymph node, left pelvic, excision - One of fifteen lymph nodes positive for metastatic carcinoma (1/15).
-

[page 6 of 6]
DIAGNOSIS

micropapillary pattern.

Tumor is present on the surface of the ovary.

Fallopian tube negative for tumor.

C. Uterus and cervix, hysterectomy - Atrophic endometrium.

Myometrium with no significant histopathologic abnormality.

Cervix with acute and chronic inflammation and reactive changes.

D. Omentum, excision - Three lymph nodes negative for metastatic carcinoma (0/3).

Adipose tissue with chronic inflammation and reactive mesothelium.

E. Soft tissue, omental lymph node, excision - Adipose tissue with metastatic serous carcinoma and chronic inflammation.

F. Soft tissue, right gutter peritoneum, biopsy - Metastatic serous carcinoma.

G. Lymph nodes, para-aortic, excision - One of six lymph nodes positive for metastatic adenocarcinoma(1/6).

H. Lymph node, right pelvic, excision - Eight lymph nodes negative for metastatic carcinoma (0/8).

I. Lymph node, left pelvic, excision - One of fifteen lymph nodes positive for metastatic carcinoma (1/15).

Source: NCI Genomic Data Commons file c6795af1-4cb3-4dfb-88fc-6c40a57783b1 (TCGA-42-2591.F4C9E6C0-C6BF-4793-A5DE-C85C347B4097.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).